HCMI case HCM-BROD-0711-C64 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8ed2333b-d19c-4fa1-9433-f349a91159bf

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1955; Vital status: Alive.

Diagnoses (1)
1. Renal cell carcinoma, chromophobe type: ICD-O-3 morphology code: 8317/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Classification of tumor: primary; Age at diagnosis: 63.8 years (23,306 days); AJCC staging edition: 8th; AJCC clinical stage: Stage II; AJCC pathologic T: T2a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Tumor grade: GX; Prior treatment: No; Residual disease: RX; Sites of involvement: Kidney, Upper Pole; Tumor focality: Unifocal.
   Pathology details: Lymph nodes positive: 0; Lymph nodes tested: 2; Lymphatic invasion present: No; Margin status: Uninvolved; Necrosis present: Yes; Rhabdoid present: No; Sarcomatoid present: No; Tumor largest dimension diameter: 9.5 cm; Vascular invasion present: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 37 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Chemotherapy, for residual disease; adjuvant Hormone Therapy, for residual disease; adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (2 entries)
- Days to follow up: 742 days (2.0 years); Disease response: Complete Response; Progression or recurrence: No.
- Follow-up contact recording only the day: day 392.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 86 kg; Height: 185 cm; BMI: 25.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-BROD-0711-C64-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-BROD-0711-C64-01A-01-S1-HE: Section location: Top; Percent tumor cells: 55; Percent tumor nuclei: 94; Percent normal cells: 0; Percent necrosis: 24; Percent stromal cells: 21; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-BROD-0711-C64-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 60; Percent tumor nuclei: 92; Percent normal cells: 0; Percent necrosis: 20; Percent stromal cells: 20; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-BROD-0711-C64-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0711-C64-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 12.
